MMRF case MMRF_1346 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6708920e-ecd2-4682-8a33-52a64b710f03

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.7 years (23,271 days); ISS stage: II; Days to last known disease status: 427 days (1.2 years); Days to last follow up: 427 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 62 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 0): M Protein 7.5 g/dL; Immunoglobulin G 26.3 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 5.38 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 367 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7.5 g/dL; Glucose 4.24 mmol/L; C-Reactive Protein 0.01 mg/dL.
- Day 69 (ECOG 0): Hemoglobin 5.08 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 14.9 mmol/L.
- Day 147 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Immunoglobulin G 24.3 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 4.23 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 616 ×10⁹/L; Creatinine 216 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 4.57 mmol/L.
- Day 272 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 687 mg/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.59 µg/mL; Hemoglobin 5.52 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 466 ×10⁹/L; Creatinine 184 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 8.91 mmol/L.
- Day 342 (ECOG 1): M Protein 2.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.1 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 5.77 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 608 ×10⁹/L; Creatinine 211 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 3.63 mmol/L.
- Day 427 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 82.3 mg/dL; Immunoglobulin G 35.7 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 7 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 458 ×10⁹/L; Creatinine 230 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 8.3 g/dL; Glucose 13.1 mmol/L.

Other clinical attributes
- Day -30: Weight: 49 kg; Height: 149 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1346_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
